Somatic mutation profile of tumor specimen TCGA-S9-A7IQ-01A (aliquot TCGA-S9-A7IQ-01A-21D-A34A-08) from TCGA case TCGA-S9-A7IQ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 45.2 years (16,512 days).
Specimen TCGA-S9-A7IQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04adba93-3e7b-40ae-85c7-4eb1ceb91cb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A7IQ-10A (Blood Derived Normal), aliquot TCGA-S9-A7IQ-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6d35858-5a4a-4456-ad41-c5149b18b15d

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/122 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- C1orf158 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1380537297, COSV99847259; called by muse, mutect2, varscan2
- CKM | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs763411131, COSV53463349; called by muse, varscan2
- CPNE5 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV99782597; called by muse, mutect2
- FBN3 | c.5701G>A p.G1901S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54455660, COSV99560426; called by muse, mutect2, varscan2
- GPR132 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100317507; called by muse, mutect2, varscan2
- NR2F2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101240980; called by muse, mutect2, varscan2
- ROCK2 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV99837188; called by muse, mutect2, varscan2
- SPICE1 | c.1812G>A p.W604* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV55617667, COSV99871155; called by muse, mutect2
- SPTBN5 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs547989631, COSV100311052; called by muse, varscan2
- WDR12 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs746259580, COSV99651030; called by muse, mutect2, varscan2
- CDK12 | c.244_245dup p.F83Pfs*10 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- LRRC43 | c.747C>T p.H249= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV100336639; called by muse, mutect2, varscan2
- PSMB8 | c.525C>T p.G175= (on ENST00000374882 / NM_148919.4; = p.G171= on NM_004159.5) | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
